Gene-level copy-number profile of tumor specimen TCGA-3B-A9I0-01A from TCGA case TCGA-3B-A9I0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 33.3 years (12,148 days).
Specimen TCGA-3B-A9I0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5b0a431b-f8ac-4e83-ba2d-d88e8a437bbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9I0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96fe62ba-ee4a-42d4-bc21-949a8a8aa82d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 10,020; copy number 2: 48,723; copy number 3: 1,046; copy number 4: 21; copy number 5: 1; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9I0-01A-11D-A38Y-01): tumor purity 0.91, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:36,432,882–36,626,138, 6 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:109,760,360–109,772,043, 1 gene, copy number 5 (within-gene range 2–5): AL158829.1.
- chr19:27,638,483–27,794,005, 3 genes, copy number 6 (within-gene range 2–6): ERVK-28, AC112702.1, LINC00662.

Autosomal genes at a single copy (total copy number 1): 7,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
